Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A5RI, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A5RI-01A (Primary Tumor).

[page 1 of 6]
Gender

F

Date Of
Birth

Encounter
Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Reported

Ordering Provider

Status

Final

Results

1CD-0-3

Carcinoma, wrothelial, NOS 8/20/13 Final
Site: bladder, posterior wall C67.4

fw
2/17/13

Source of Specimen

- A. LEFT PELVIC LYMPH NODES- FS-
- B. LEFT PELVIC LYMPH NODES-NFS-
- C. RIGHT PELVIC LYMPH NODES-FS-
- D. RIGHT PELVIC LYMPH NODES-NFS-
- E. APPENDIX-
- F. LEFT URETER MARGIN-FS-
- G. RIGHT URETER MARGIN-FS-
- H. BLADDER, UTERUS, BILATERAL FALLOPIAN TUBES SEE WORKSHEET-

FINAL DIAGNOSIS:

- A. LEFT PELVIC LYMPH NODES- FS-
THREE FATTY LYMPH NODES, NO MALIGNANCY SEEN.
- B. LEFT PELVIC LYMPH NODES-NFS-
SEE PART "A".
- C. RIGHT PELVIC LYMPH NODES-FS-
TWO FATTY LYMPH NODES, NO MALIGNANCY SEEN.
- D. RIGHT PELVIC LYMPH NODES-NFS-
SEE PART "C".
- E. APPENDIX-
VERMIFORM APPENDIX WITH NO DIAGNOSTIC ABNORMALITY SEEN.
- F. LEFT URETER MARGIN-FS-
NO CARCINOMA SEEN.
- G. RIGHT URETER MARGIN-FS-
NO CARCINOMA SEEN.
- H. BLADDER, UTERUS, BILATERAL FALLOPIAN TUBES SEE WORKSHEET-
INVASIVE CARCINOMA, HIGH GRADE.

Prepare

[page 2 of 6]
TUMOR SITE: POSTERIOR, URINARY BLADDER.

HISTOLOGIC TYPE: UROTHELIAL.

SQUAMOUS DIFFERENTIATION: NOT PRESENT.

GLANDULAR DIFFERENTIATION: IS PRESENT, EXTENSIVE.

TUMOR SIZE: 3.0 CM.

HISTOLOGIC GRADE: 3/3.

TUMOR INVADES PERIVESICAL SOFT TISSUE, MICROSCOPICALLY.

SPECIMEN TYPE: ANTERIOR EXENTERATION: RADICAL CYSTECTOMY, TOTAL
HYSTERECTOMY AND BILATERAL SALPINGOOPHORECTOMY, ANTERIOR
VAGINECTOMY.

TNM STAGE: pT3a, pN0, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED: 0
NUMBER EXAMINED: 5

LYMPHATIC (SMALL VESSEL) INVASION: IS PRESENT.

PERINEURAL INVASION: PRESENT, EXTENSIVE.

ASSOCIATED EPITHELIAL LESIONS: EXTENSIVE SURFACE ULCERATION.
MODERATE UROTHELIAL DYSPLASIA FOCALLY SEEN.

NO TUMOR SEEN AT URETERAL AND URETHRAL MARGINS.
PERIVESICAL SOFT TISSUE MARGIN: NEGATIVE FOR TUMOR.
VAGINA, UTERUS AND CERVIX: NEGATIVE FOR MALIGNANCY.

OTHER BENIGN FINDINGS: _____

ATROPHIC ENDOMETRIUM.

INTRAMURAL LEIOMYOMATA.

ATROPHIC OVARIES WITH FOCAL ENDOSALPINGIOSIS.

PARATUBAL CYSTS.

Signature

Prepar _____

[page 3 of 6]
Signed Others

Frozen Section

A. RIGHT URETER MARGIN: NO CARCINOMA.

LEFT URETER MARGIN: NO CARCINOMA.

RIGHT AND LEFT PELVIC LYMPH NODES: FATTY LYMPH NODES ON BOTH SIDES, REPRESENTATIVE SECTIONS TAKEN FOR FS.

RIGHT PELVIC LYMPH NODES: 2 FATTY LYMPH NODES. NO TUMOR SEEN (0/2).

LEFT PELVIC LYMPH NODES: 3 FATTY LYMPH NODES. NO TUMOR SEEN (0/3).

Frozen section performed by

Case Clinical Information

BLADDER CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "left pelvic lymph nodes FS" are three fatty, yellow-tan tissue fragments measuring up to 2 x 1.2 x 0.2 cm thick. The entire specimen is submitted in A1.

B. Received in formalin labeled with the patient's name and "left pelvic lymph nodes NFS" are multiple fragments of finely divided fat, measuring 3 x 3 x 3 cm in compact aggregate. Residual induration is submitted in B1-B3.

C. Received in formalin labeled with the patient's name and "right pelvic lymph nodes FS" are two elongated, fatty, pink-tan tissues measuring 2 x 1.1 x 0.2 cm thick. The entire specimen is submitted in C1.

D. Received in formalin labeled with the patient's name and "right pelvic lymph nodes NFS" are multiple fragments of finely divided fat, measuring 3 x 3 x 3 cm in compact aggregate. Residual induration is submitted in D1-D3.

F. Received in formalin labeled with the patient's name and "appendix" is a grossly unremarkable vermiform appendix with attached periappendiceal fat measuring 7 x 0.4 cm thick, with the surgical margin revealing a staple closure. The appendiceal lumen is pinpoint. A shave of the resection margin adjacent to

Prepared: _____

[page 4 of 6]
the staple closure and entire appendiceal tip is submitted in E1.

F. Received in formalin labeled with the patient's name and "left ureter FS" is yellow tan, soft tissue measuring 1 x 1 x 0.2 cm. Totally submitted in F1.

G. Received in formalin labeled with the patient's name and "right ureter FS" is yellow-tan, soft tissue measuring 9 x 6 x 1 mm thick. The specimen is submitted totally in G1.

H. Received in formalin labeled with the patient's name and "uterus, bilateral tubes and ovaries, bladder, anterior vaginal wall" is a specimen so designated, measuring overall 13 cm superior to inferior, 10 cm right to left, 8 cm anterior to posterior. The uterus and cervix measure 7 cm superior to inferior, 4.5 cm right to left, 2.2 cm anterior to posterior. Unremarkable right and left fallopian tubes, measuring 6.5 x 0.6 and 6 x 0.5 cm with unremarkable, atrophic appearing right and left ovaries measuring 2 x 1.5 x 0.6 and 2 x 1.5 x 0.6 cm in greatest dimensions. The included portion of anterior vaginal wall is continuous with the perineal and distal urethral mucosa, it measures up to 5 cm in width superiorly and appears unremarkable. The cervix is 3 cm in diameter with a 1.2 cm linear os. The specimen previously has been inked blue on the left, black on the right, and the bladder cavity is exposed. The bladder wall appears indurated with a diminished bladder cavity measuring 2.5 cm right to left, superior to inferior, 2 cm anterior to posterior. The posterior superior aspect of the bladder is replaced by an area of ulceration and induration, measuring 3 x 3 cm. Section code: H1=distal urethra; H2=shaved entire left vaginal resection margin; H3=shaved entire right vaginal resection margin; H4=left cross sections mid urethra; H5=right mid urethral cross sections; H6=half left ovary; H7=left fallopian tube; H8=half of right ovary; H9=right fallopian tube; H10=posterior cervix; H11=anterior cervix; H12-H13=anterior posterior uterine wall, including thin endometrium and two fibroid-like nodules with uterine cavity measuring 1.2 cm in width, 2 cm in length; H14-H18=extensive sampling of bladder tumor, which measures up to 2 cm thick, deeply penetrating posterior bladder fat. H19-H20=tumor to inked left posterior soft tissue margin. The included stubs of ureter are deeply retracted and are not sampled at this time due to their presence in parts F1 and G1

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK

H&E X1

B. AA ROUTINE H&E X1 BLOCK.1

Prepared

[page 5 of 6]
H&E X1
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1
F. AA ROUTINE H&E X1 BLOCK
H&E X1
G. AA ROUTINE H&E X1 BLOCK
H&E X1
H. AA ROUTINE H&E X1 BLOCK.1
H&E X1
H. AA ROUTINE H&E X1 BLOCK.2
H&E X1 A RECUTS
H. AA ROUTINE H&E X1 BLOCK.3
H&E X1 A RECUTS
H. AA ROUTINE H&E X1 BLOCK.4
H&E X1
H. AA ROUTINE H&E X1 BLOCK.5
H&E X1
H. AA ROUTINE H&E X1 BLOCK.6
H&E X1
H. AA ROUTINE H&E X1 BLOCK.7
H&E X1
H. AA ROUTINE H&E X1 BLOCK.8
H&E X1
H. AA ROUTINE H&E X1 BLOCK.9
H&E X1
H. AA ROUTINE H&E X1 BLOCK.10
H&E X1 A RECUTS
H. AA ROUTINE H&E X1 BLOCK.11
H&E X1
H. AA ROUTINE H&E X1 BLOCK.12
H&E X1
H. AA ROUTINE H&E X1 BLOCK.13
H&E X1
H. AA ROUTINE H&E X1 BLOCK.14
H&E X1
H. AA ROUTINE H&E X1 BLOCK.15

[page 6 of 6]
H&E X1
H. AA ROUTINE H&E X1 BLOCK.16
H&E X1
H. AA ROUTINE H&E X1 BLOCK.17
H&E X1
H. AA ROUTINE H&E X1 BLOCK.18
H&E X1
H. AA ROUTINE H&E X1 BLOCK.19
H&E X1
H. AA ROUTINE H&E X1 BLOCK.20
H&E X1

Prepared

HISTOLOGY Discrepancy		
Qual/Syn/Chronous Primary Note		

Source: NCI Genomic Data Commons file 3f8d43fe-271f-457c-bb8b-e05a9f36dd9a (TCGA-K4-A5RI.F61654B9-A305-40B9-97FE-A22B9EE1375D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).